Somatic mutation profile of tumor specimen TCGA-AA-A024-01A (aliquot TCGA-AA-A024-01A-02W-A00E-09) from TCGA case TCGA-AA-A024, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 81.3 years (29,708 days).
Specimen TCGA-AA-A024-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 761e7654-6445-42bd-8f44-95719aab4db1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A024-10A (Blood Derived Normal), aliquot TCGA-AA-A024-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d249695-753c-4673-988f-9f60be979e91

The open-access MAF lists 83 somatic variants for this specimen: 61 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 17, Nonsense Mutation 8, Intron 3, Splice Region 1, In Frame Ins 1, 3'UTR 1, Frame Shift Del 1, Splice Site 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as rs587779780, CD042580, CM920031, COSV57322404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4669_4670del p.I1557* | Frame Shift Del (DEL) | VAF 145/397 reads (37%) | catalogued as rs786201118; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1514G>A p.R505H (on ENST00000281708 / NM_001349798.2; = p.R425H on NM_018315.5) | Missense Mutation (SNP) | VAF 59/163 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 57/94 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 45/60 reads (75%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- ACAP1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs756716611, COSV50135201; called by muse, mutect2, varscan2
- ADAM2 | c.1862G>A p.C621Y | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55868807; called by muse, mutect2, varscan2
- ADGRA3 | c.3556G>A p.V1186I | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV51568634; called by muse, mutect2, varscan2
- ALDH18A1 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64663458; called by muse, mutect2
- ATP2B4 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs779728673, COSV58184245; called by muse, mutect2
- AWAT1 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65738764, COSV65739120; called by muse, mutect2, varscan2
- CNTNAP4 | c.324C>A p.S108R | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV56701379; called by muse, mutect2, varscan2
- COL5A3 | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs753887905, COSV53419688; called by muse, mutect2, varscan2
- COL9A1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs778243284, COSV61828847; called by muse, mutect2, varscan2
- DMD | c.6599C>G p.S2200* | Nonsense Mutation (SNP) | VAF 130/191 reads (68%) | catalogued as COSV58955498; called by muse, mutect2, varscan2
- EVC2 | c.3809A>G p.E1270G | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60403173; called by muse, mutect2
- FAM47C | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.119); catalogued as rs1556331362, COSV63729924; called by muse, mutect2, varscan2
- FLG | c.2318A>G p.Q773R | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64249972; called by muse, mutect2, varscan2
- GRIP2 | c.1052C>T p.T351M (on ENST00000619221; = p.T254M on NM_001080423.4) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs763795271, COSV56124863; called by muse, mutect2, varscan2
- H1-1 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV55119419; called by muse, mutect2, varscan2
- HECTD4 | c.10891A>G p.I3631V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.982); catalogued as rs1027303965, COSV66400212; called by muse, mutect2, varscan2
- HSPA1L | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.738); catalogued as rs768126334, COSV65148681; called by muse, mutect2, varscan2
- IFIT1B | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 110/361 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV65663253; called by muse, mutect2, varscan2
- IGF2BP3 | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV51693826; called by muse, mutect2, varscan2
- INSL6 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs373690238, COSV67563254; called by muse, mutect2, varscan2
- INTS2 | c.2672A>G p.Y891C | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV52156872; called by muse, mutect2, varscan2
- IYD | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.611); catalogued as rs370872496; called by muse, mutect2, varscan2
- KCNA5 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52908892; called by muse, mutect2
- KIT | c.2836C>T p.R946* | Nonsense Mutation (SNP) | VAF 75/176 reads (43%) | catalogued as rs139000082, COSV55391358; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRTAP11-1 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.69); catalogued as COSV60095511; called by muse, mutect2, varscan2
- LAMB4 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs1225903691, COSV52731636; called by muse, mutect2, varscan2
- MARK1 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as rs750355718, COSV100857474, COSV65065258; called by muse, mutect2, varscan2
- MGA | c.7276C>G p.R2426G (on ENST00000219905 / NM_001164273.1; = p.R2217G on NM_001080541.2) | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV54963629; called by muse, mutect2, varscan2
- NLRP8 | c.533_535del p.F178del | In Frame Del (DEL) | VAF 36/78 reads (46%) | catalogued as rs773103156; called by pindel, varscan2
- NUP133 | c.790G>T p.G264* | Nonsense Mutation (SNP) | VAF 44/137 reads (32%) | catalogued as COSV54575473; called by muse, mutect2, varscan2
- OLFM3 | c.907T>A p.Y303N (on ENST00000338858 / NM_001288821.1; = p.Y283N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/160 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV58804582; called by muse, mutect2, varscan2
- OR2A12 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 38/401 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV68822080; called by muse, mutect2, varscan2
- OR8B4 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.21); catalogued as rs778477965, COSV62070624; called by muse, mutect2, varscan2
- PAK5 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 87/247 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV62038479; called by muse, mutect2, varscan2
- PCDHA13 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.048); catalogued as rs782467193, COSV56496419, COSV56539642; called by muse, mutect2
- PCDHGA3 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.223); catalogued as COSV53897290; called by muse, mutect2, varscan2
- PLEKHA5 | c.3133G>A p.A1045T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748283572, COSV54713066; called by muse, mutect2, varscan2
- RBM43 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 154/398 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as COSV58878201, COSV58879980; called by muse, mutect2, varscan2
- RIMS2 | c.2470C>T p.R824* (on ENST00000666250 / NM_001348490.2; = p.R632* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 62/173 reads (36%) | catalogued as rs561377229, COSV51662074, COSV51700955; called by muse, mutect2, varscan2
- SLC7A14 | c.306C>T p.G102= | Splice Region (SNP) | VAF 13/44 reads (30%) | catalogued as rs777951463, COSV51584442; called by muse, mutect2, varscan2
- SNRNP27 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1377409209, COSV54912920; called by muse, mutect2, varscan2
- TCERG1 | c.3228T>A p.D1076E | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV57042256; called by muse, mutect2, varscan2
- THAP12 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 111/296 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0.143); catalogued as COSV52613248; called by muse, mutect2, varscan2
- TOPORS | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 38/99 reads (38%) | catalogued as COSV62118322; called by muse, mutect2, varscan2
- TPP1 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs140176031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM44 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV54987684; called by mutect2, varscan2
- WSCD2 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as COSV54584319; called by muse, mutect2, varscan2
- ZNF417 | c.1333T>A p.F445I | Missense Mutation (SNP) | VAF 116/313 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56310087; called by muse, mutect2, varscan2
- ZWINT | c.541A>T p.T181S | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.178); catalogued as COSV59186407; called by muse, mutect2, varscan2
- ARFGEF1 | c.4475-1G>C p.X1492_splice | Splice Site (SNP) | VAF 51/149 reads (34%) | called by muse, mutect2, varscan2
- CHD7 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2
- CHD7 | c.1461C>A p.D487E | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); called by muse, mutect2
- DMXL2 | c.7684G>T p.D2562Y | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- DROSHA | c.1301_1309dup p.V436_G437insAVV | In Frame Ins (INS) | VAF 61/230 reads (27%) | called by mutect2, varscan2
- OSMR | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.071); called by muse, mutect2
- SDK2 | c.5534C>A p.S1845Y | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by mutect2, varscan2
- ADD2 | c.1575C>T p.A525= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs201133279, COSV52462607; called by muse, mutect2, varscan2
- C6orf118 | c.975G>A p.P325= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs369772945, COSV57819679; called by muse, varscan2
- CCR9 | c.612C>T p.S204= (on ENST00000357632 / NM_031200.3; = p.S192= on NM_006641.4) | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs771948402, COSV62940850; called by muse, mutect2, varscan2
- CTNNA3 | c.1107G>A p.K369= | Silent (SNP) | VAF 194/564 reads (34%) | catalogued as COSV65555168, COSV65621489; called by muse, mutect2, varscan2
- NPAP1 | c.399G>A p.P133= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs750902724, COSV61504850; called by muse, mutect2, varscan2
- PCDHA13 | c.1533C>T p.H511= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs782690228, COSV56479536; called by muse, mutect2, varscan2
- PCDHA13 | c.2046G>A p.A682= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV56500528; called by muse, mutect2, varscan2
- PCDHA6 | c.288C>T p.C96= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs782510418, COSV65350472; called by muse, mutect2, varscan2
- PPP1R17 | c.294C>A p.G98= | Silent (SNP) | VAF 68/179 reads (38%) | catalogued as COSV100566372, COSV59612647; called by muse, mutect2, varscan2
- PUM1 | c.2199C>T p.N733= | Silent (SNP) | VAF 136/194 reads (70%) | catalogued as rs1465195390, COSV57091607; called by muse, mutect2, varscan2
- ROCK1 | c.2976C>T p.I992= | Silent (SNP) | VAF 119/269 reads (44%) | catalogued as rs375431349, COSV67699546; called by muse, mutect2, varscan2
- SCNM1 | c.261G>A p.Q87= | Silent (SNP) | VAF 48/159 reads (30%) | catalogued as COSV54862069; called by muse, mutect2, varscan2
- TBCCD1 | c.813A>C p.T271= | Silent (SNP) | VAF 55/122 reads (45%) | catalogued as COSV58663664; called by muse, mutect2, varscan2
- TMEM39A | c.1194C>T p.N398= | Silent (SNP) | VAF 65/177 reads (37%) | catalogued as rs1261762527, COSV59901010; called by muse, mutect2, varscan2
- USH2A | c.11466C>T p.S3822= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs144655434; ClinVar: likely benign; called by muse, mutect2
- WSCD2 | c.918G>A p.A306= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs367674517; called by muse, mutect2, varscan2
- ZSCAN16 | c.1014T>C p.H338= | Silent (SNP) | VAF 61/175 reads (35%) | catalogued as COSV61259143; called by muse, mutect2, varscan2
- CPLANE1 | c.*5663_*5699del | 3'UTR (DEL) | VAF 38/152 reads (25%) | called by mutect2, pindel
- CTBP2 | c.58+11304G>A | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as rs1365402174, COSV58338978; called by muse, mutect2, varscan2
- KRT4 | c.-7T>C | 5'UTR (SNP) | VAF 9/34 reads (26%) | catalogued as COSV53409900; called by muse, mutect2, varscan2
- SV2C | c.581-21048C>G | Intron (SNP) | VAF 54/174 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.10360+4011C>T | Intron (SNP) | VAF 72/209 reads (34%) | called by muse, mutect2, varscan2
